Somatic mutation profile of tumor specimen TCGA-38-4628-01A (aliquot TCGA-38-4628-01A-01D-1265-08) from TCGA case TCGA-38-4628, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.9 years (24,057 days).
Specimen TCGA-38-4628-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1ed9214-b0e9-44be-9517-bd8d771d1d0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-4628-11A (Solid Tissue Normal), aliquot TCGA-38-4628-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43ef9d3f-7b63-4369-b66c-0bbdf5ca3a84

The open-access MAF lists 133 somatic variants for this specimen: 103 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 28, Nonsense Mutation 7, Frame Shift Del 4, In Frame Del 2, Intron 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 36/110 reads (33%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ANO5 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61088911, COSV61091584; called by muse, mutect2, varscan2
- ARHGEF40 | c.1146G>C p.K382N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV53881526; called by muse, mutect2, varscan2
- ARID3B | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1053752911, COSV60556853; called by muse, mutect2, varscan2
- BAG6 | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV52993842; called by muse, mutect2, varscan2
- BRINP1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1473785, COSV56292284, COSV56310660; called by muse, mutect2, varscan2
- C15orf48 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV60223624; called by muse, mutect2, varscan2
- CCDC178 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55790400; called by muse, mutect2, varscan2
- CCDC28B | c.158T>C p.F53S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV52210647; called by muse, mutect2, varscan2
- CCDC87 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs1403883179, COSV59578508, COSV59579748; called by muse, varscan2
- CD200 | c.870G>C p.Q290H (on ENST00000473539 / NM_001004196.3; = p.Q265H on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59864199; called by muse, varscan2
- CDK12 | c.1274T>C p.V425A | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs1363432646, COSV71002247; called by muse, mutect2, varscan2
- CHRNA4 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286318558, COSV64718022; called by muse, mutect2, varscan2
- CLEC4F | c.1624G>C p.D542H | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55480831; called by muse, mutect2, varscan2
- CLVS1 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV57980748; called by muse, mutect2, varscan2
- CP | c.2102C>T p.T701I | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52832934; called by muse, mutect2, varscan2
- CRTC2 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV57845070; called by muse, mutect2, varscan2
- CYBB | c.337G>C p.A113P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV66086047; called by muse, mutect2, varscan2
- CYYR1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1371255873, COSV54836151, COSV99051262; called by muse, mutect2, varscan2
- DIS3 | c.2816C>G p.T939S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV64697046; called by muse, mutect2, varscan2
- DNAH11 | c.8316A>T p.E2772D | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.037); catalogued as COSV60973243; called by muse, mutect2, varscan2
- DNAH5 | c.9227G>T p.S3076I | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV54244439; called by muse, mutect2, varscan2
- DNTTIP2 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV63284450; called by muse, mutect2, varscan2
- DPY19L2 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV60545210, COSV60545274; called by muse, mutect2
- EIF4B | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV50406004; called by muse, mutect2, varscan2
- ELF1 | c.1460A>T p.Q487L | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV53501283; called by muse, mutect2, varscan2
- EPHA6 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.976); catalogued as COSV67588300; called by muse, mutect2
- FAM111B | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100639334, COSV59113099; called by muse, mutect2
- FBXL7 | c.650T>G p.L217R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61650840; called by mutect2, varscan2
- FCRL3 | c.776G>A p.W259* | Nonsense Mutation (SNP) | VAF 19/144 reads (13%) | catalogued as COSV63844016; called by muse, mutect2, varscan2
- FLG2 | c.6478T>A p.S2160T | Missense Mutation (SNP) | VAF 114/623 reads (18%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.831); catalogued as COSV66171641; called by muse, mutect2, varscan2
- FMO4 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 107/541 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as rs770117618, COSV63000604; called by muse, mutect2, varscan2
- GDI1 | c.675A>T p.L225F | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50132646; called by muse, mutect2, varscan2
- GLYATL1 | c.669G>T p.M223I (on ENST00000317391 / NM_001354699.1; = p.M254I on NM_080661.4) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV55610652, COSV55611802; called by muse, mutect2, varscan2
- IL1RAPL2 | c.2017C>A p.P673T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as COSV61172172, COSV61173580; called by muse, mutect2, varscan2
- KCNK2 | c.178A>T p.K60* (on ENST00000444842 / NM_001017425.3; = p.K45* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 52/94 reads (55%) | catalogued as COSV67208839; called by muse, mutect2, varscan2
- KIR2DL3 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100668028; called by muse, mutect2, varscan2
- LAMB1 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55968824; called by muse, mutect2, varscan2
- LCE3C | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 58/708 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100425265; called by muse, mutect2
- LRRIQ1 | c.2063G>A p.S688N | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV67836241; called by muse, mutect2, varscan2
- MAPT | c.1175A>C p.H392P (on ENST00000262410 / NM_001377265.1; = p.H317P on NM_016835.4) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV52245637; called by muse, mutect2, varscan2
- MCF2 | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as rs921045098, COSV58492194; called by muse, mutect2, varscan2
- MGA | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV54955602, COSV54960568; called by muse, mutect2, varscan2
- MRPL18 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | catalogued as rs1291041199, COSV51706535; called by muse, mutect2, varscan2
- MTMR8 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66395677; called by muse, mutect2, varscan2
- NGEF | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV50942687; called by muse, mutect2, varscan2
- NISCH | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51768206; called by muse, mutect2, varscan2
- NPAS4 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV60652055; called by muse, mutect2, varscan2
- NUBPL | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as rs1238368059, COSV55273114; called by muse, mutect2
- NUMA1 | c.5069C>G p.A1690G | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV59644522; called by muse, mutect2
- OR4K5 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV60004735; called by muse, mutect2
- OR52M1 | c.300G>T p.L100F | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64172544; called by muse, mutect2, varscan2
- PCDHA7 | c.334A>T p.R112W | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV65346519; called by muse, mutect2, varscan2
- PCDHAC2 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1554228854, COSV99145613, COSV99152764; called by muse, mutect2
- PDZRN4 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV68413867; called by muse, varscan2
- PNISR | c.2143C>T p.R715* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV65080376; called by muse, mutect2
- POLR2M | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100221332; called by muse, mutect2, varscan2
- PPP1R13L | c.2396G>A p.W799* | Nonsense Mutation (SNP) | VAF 20/112 reads (18%) | catalogued as COSV62909315; called by muse, mutect2, varscan2
- PPP6R2 | c.1735T>G p.F579V (on ENST00000216061 / NM_001365836.1; = p.F552V on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53296985; called by muse, mutect2, varscan2
- PRUNE2 | c.2815G>T p.D939Y | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs772854166, COSV65045772; called by muse, mutect2, varscan2
- PTPN6 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV59685786; called by muse, mutect2, varscan2
- RALGAPA1 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51892791; called by muse, mutect2, varscan2
- RANBP17 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV66655071; called by muse, mutect2, varscan2
- RHPN2 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV54283095; called by muse, mutect2, varscan2
- RIMS2 | c.4490G>T p.R1497I (on ENST00000666250 / NM_001348490.2; = p.R1068I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51710973; called by muse, mutect2, varscan2
- RNF148 | c.196T>A p.S66T | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57379166; called by muse, mutect2, varscan2
- RPL4 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1354217849, COSV57182193; called by muse, mutect2
- RWDD2B | c.846C>A p.F282L | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs796086018, COSV99725698; called by muse, mutect2, varscan2
- SALL1 | c.1190C>A p.S397Y | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV51762560; called by muse, mutect2
- SALL1 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs772476680, COSV51753884; called by muse, mutect2
- SCGN | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV58546679; called by muse, mutect2, varscan2
- SEMA3D | c.428T>G p.I143R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV52401130, COSV99406734; called by muse, mutect2, varscan2
- SERPINA11 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58242833; called by muse, mutect2, varscan2
- SFMBT2 | c.1247C>A p.A416D | Missense Mutation (SNP) | VAF 87/150 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV62806131, COSV62814534; called by muse, mutect2, varscan2
- SNX12 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV52146457; called by muse, mutect2
- SPATA22 | c.995G>T p.R332I | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52153877; called by muse, mutect2
- SPIRE1 | c.496G>C p.A166P | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV100564167, COSV59161143; called by muse, mutect2, varscan2
- STN1 | c.671T>G p.F224C | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56545694; called by muse, mutect2, varscan2
- SUN1 | c.1975+1G>A p.X659_splice (on ENST00000405266 / NM_001367651.1; = p.X539_splice on NM_025154.6 and 13 other RefSeq transcripts) | Splice Site (SNP) | VAF 57/135 reads (42%) | catalogued as COSV67451393; called by muse, mutect2, varscan2
- SYTL4 | c.1057A>T p.N353Y | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52170341; called by muse, mutect2, varscan2
- TBX21 | c.1494G>C p.K498N | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51597585; called by muse, mutect2, varscan2
- TBX22 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV64787384; called by muse, mutect2
- TDP1 | c.1703C>G p.A568G | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV59645015; called by muse, mutect2, varscan2
- TLR6 | c.1843C>G p.L615V | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV67935620; called by muse, mutect2
- TUBA1C | c.1067A>G p.N356S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV56511469; called by muse, mutect2, varscan2
- UBN2 | c.1619T>C p.L540P | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56034282; called by muse, mutect2, varscan2
- YEATS2 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs370579078, COSV100528114; called by muse, mutect2, varscan2
- ZFYVE26 | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.575); catalogued as COSV61330970, COSV61332245; called by muse, mutect2, varscan2
- ZNF536 | c.986C>A p.A329D | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.719); catalogued as COSV62828018, COSV62831316; called by muse, mutect2
- ZNF577 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV56817297; called by muse, mutect2
- ZNF630 | c.650C>A p.A217D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs200370530, COSV52097761; called by muse, mutect2
- ZNF711 | c.2149T>A p.S717T | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52157539; called by muse, mutect2, varscan2
- ZNF804B | c.3818C>T p.A1273V | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV60829219; called by muse, mutect2, varscan2
- AGPAT2 | c.554A>T p.K185M | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AGPAT2 | c.552del p.F184Lfs*69 | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | called by mutect2, pindel, varscan2
- GCN1 | c.5757dup p.R1920Afs*2 | Frame Shift Ins (INS) | VAF 22/89 reads (25%) | called by mutect2, pindel, varscan2
- H4C2 | c.214_222del p.T72_T74del | In Frame Del (DEL) | VAF 17/113 reads (15%) | called by mutect2, pindel, varscan2
- HNRNPC | c.520_532del p.N174Dfs*11 (on ENST00000420743; = p.N161Dfs*11 on NM_004500.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/185 reads (12%) | called by mutect2, pindel
- IGKV1-27 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NLRP14 | c.2413del p.L805Ffs*6 | Frame Shift Del (DEL) | VAF 21/189 reads (11%) | called by mutect2, varscan2
- NLRP14 | c.2417del p.L806Cfs*5 | Frame Shift Del (DEL) | VAF 21/211 reads (10%) | called by mutect2*, pindel, varscan2*
- SPATA31A1 | c.3536A>G p.K1179R | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SUPT20HL1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ATP4A | c.105G>T p.G35= | Silent (SNP) | VAF 26/428 reads (6%) | catalogued as COSV52870751; called by muse, mutect2
- ATP8A2 | c.2431C>A p.R811= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV54937988, COSV54969698; called by muse, mutect2, varscan2
- CHMP4B | c.606A>G p.K202= | Silent (SNP) | VAF 56/309 reads (18%) | catalogued as COSV99459973; called by muse, mutect2, varscan2
- DPAGT1 | c.318C>T p.C106= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV62615007; called by muse, mutect2, varscan2
- FBXO38 | c.582A>G p.L194= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV57030585; called by muse, mutect2, varscan2
- FMN2 | c.3528G>A p.P1176= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs183336748, COSV60445930; called by muse, varscan2
- GABRD | c.1074C>T p.N358= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs75511732, COSV66081552; called by muse, mutect2, varscan2
- GSE1 | c.1938G>T p.L646= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV53674871; called by muse, mutect2, varscan2
- IGSF10 | c.6654C>T p.P2218= | Silent (SNP) | VAF 45/149 reads (30%) | catalogued as COSV56391842; called by muse, mutect2, varscan2
- KCNJ4 | c.114G>A p.K38= | Silent (SNP) | VAF 114/277 reads (41%) | catalogued as COSV57858254; called by muse, mutect2, varscan2
- KIF4A | c.1278G>A p.A426= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1486320460, COSV65544994; called by muse, mutect2, varscan2
- MBTPS2 | c.162T>A p.T54= | Silent (SNP) | VAF 38/258 reads (15%) | catalogued as COSV63412212; called by muse, varscan2
- MGAT2 | c.234G>T p.A78= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100023610; called by muse, varscan2
- MYCBP2 | c.4719T>C p.D1573= (on ENST00000357337; = p.D1611= on NM_015057.5) | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV62033610; called by muse, mutect2, varscan2
- PARP14 | c.5076C>T p.V1692= | Silent (SNP) | VAF 44/64 reads (69%) | catalogued as COSV71735372; called by muse, mutect2, varscan2
- POLR2B | c.2847T>C p.Y949= | Silent (SNP) | VAF 51/144 reads (35%) | catalogued as COSV58902139; called by muse, mutect2, varscan2
- PRKCD | c.1479G>A p.G493= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV100388032; called by muse, mutect2
- PRRT2 | c.981C>A p.I327= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as CM1211005, COSV99569827; called by muse, mutect2
- RNF135 | c.999G>A p.E333= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100104187; called by muse, mutect2, varscan2
- RSPO1 | c.219C>T p.G73= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs375442568, COSV100740641; called by muse, mutect2
- RYR1 | c.11346C>T p.I3782= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV62106677; called by muse, mutect2
- SSC4D | c.810C>T p.S270= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1206362774, COSV51883697; called by muse, mutect2, varscan2
- TRAF6 | c.418T>C p.L140= | Silent (SNP) | VAF 43/173 reads (25%) | catalogued as COSV61923351; called by muse, mutect2, varscan2
- TRPM2 | c.2361C>T p.R787= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as rs745395387, COSV55971734; called by muse, mutect2
- TTN | c.19122A>T p.I6374= (on ENST00000591111; = p.I5447= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100624429; called by muse, mutect2, varscan2
- TYMS | c.594C>G p.L198= | Silent (SNP) | VAF 40/222 reads (18%) | catalogued as COSV51894775, COSV99201130; called by muse, mutect2, varscan2
- VPS35L | c.2538C>T p.N846= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1040979714, COSV51988967; called by muse, mutect2, varscan2
- ZNF831 | c.1968G>T p.L656= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as COSV64043780; called by muse, varscan2
- EME2 | c.569+18G>A | Intron (SNP) | VAF 16/147 reads (11%) | catalogued as rs1197745671, COSV99169536; called by muse, mutect2, varscan2
- EME2 | c.569+19C>A | Intron (SNP) | VAF 16/145 reads (11%) | catalogued as COSV99169537; called by muse, mutect2, varscan2
